Somatic mutation profile of tumor specimen TARGET-10-PARMUC-03A (aliquot TARGET-10-PARMUC-03A-01D) from TARGET case TARGET-10-PARMUC, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (968 days).
Specimen TARGET-10-PARMUC-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1e02b34-b8b1-4fdf-a813-60b6a8dad068.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARMUC-14A (Bone Marrow Normal), aliquot TARGET-10-PARMUC-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64d66398-5fc3-4b44-87cb-92c8233282ad

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 1, Frame Shift Ins 1, 3'Flank 1, Frame Shift Del 1, 3'UTR 1, RNA 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.5293del p.Q1765Rfs*6 | Frame Shift Del (DEL) | VAF 15/49 reads (31%) | catalogued as COSV52123404; called by mutect2, pindel, varscan2
- MAP3K4 | c.4096G>A p.G1366R | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100815616, COSV62329900; called by muse, mutect2, varscan2
- NOTCH1 | c.4721T>C p.L1574P | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53024760, COSV53072929; called by muse, mutect2
- RANBP17 | c.3220C>T p.R1074C | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs748673739, COSV66643784; called by muse, mutect2, varscan2
- TMPRSS11B | c.774dup p.H259Sfs*2 | Frame Shift Ins (INS) | VAF 30/88 reads (34%) | catalogued as rs1450492191; called by mutect2, pindel, varscan2
- SREBF2 | c.489_492delinsCCATCGCCGGGGG p.R163_I164delinsSHRRG | In Frame Ins (INS) | VAF 27/119 reads (23%) | called by pindel, varscan2*
- ST7 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- CHD5 | c.2259G>C p.L753= | Silent (SNP) | VAF 64/138 reads (46%) | called by muse, mutect2, varscan2
- BIRC8 | n.1057C>T | RNA (SNP) | VAF 36/86 reads (42%) | catalogued as rs756944611, COSV70346390; called by muse, mutect2, varscan2
- CC2D2B | chr10:96032928 C>A | 3'Flank (SNP) | VAF 6/16 reads (38%) | called by muse, varscan2
- ZC3H18 | c.*225C>T | 3'UTR (SNP) | VAF 19/44 reads (43%) | called by muse, mutect2, varscan2
